CPTAC case SC-0500 — Skin — Nevi and Melanomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5861a90a-b5e4-466c-b104-a3752d54d105

Demographics
Sex at birth: female; Vital status: Alive.

Diagnoses (1)
1. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin of other and unspecified parts of face; Age at diagnosis: 89.0 years (32,507 days); AJCC staging edition: 8th; AJCC pathologic T: T4b; AJCC pathologic N: NX; AJCC pathologic M: M0; Progression or recurrence: no; Days to last follow up: 122 days; Clark level: V.
   Pathology details: Breslow thickness: 11.

Biospecimens (1 sample)
- Sample S-1911-009342: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Frozen; Initial weight: 274 mg; Method of sample procurement: Tumor Resection.
